Surgical pathology report (de-identified scan), TCGA case TCGA-N6-A4V9, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of Pittsburgh, specimen TCGA-N6-A4V9-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY -
BENIGN OMENTAL ADIPOSE TISSUE.

PART 2: UTERUS, CERVIX AND BILATERAL ADNEXA (172 grams), HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- MALIGNANT MIXED MULLERIAN TUMOR (CARCINOSARCOMA) (see comment).
- THE TUMOR INVADES 18% OF THE MYOMETRIAL THICKNESS (0.2 cm INVASION OF 1.1 cm THICK MYOMETRIUM).
- THE TUMOR INVOLVES A PRE-EXISTING SUBMUCOSAL LEIOMYOMA.
- THE TUMOR MEASURES 7.2 CM IN LARGEST DIMENSION AND IS PRESENT AS A POLYPOID MASS IN THE ENDOMETRIAL CAVITY.
- CERVIX IS NEGATIVE FOR TUMOR.
- NO DEFINITE LYMPHOVASCULAR SPACE INVASION IS IDENTIFIED (see comment).
- THE BACKGROUND ENDOMETRIUM IS INACTIVE.
- THE MYOMETRIUM SHOWS LEIOMYOMAS.
- ALL ADNEXAE ARE NEGATIVE FOR TUMOR.
- THE LEFT PARATUBAL TISSUE SHOWS A LIPOMA.

PART 3: ABDOMINAL PERITONEUM, RIGHT, BIOPSY -
FIBROADIPOSE TISSUE, NO TUMOR PRESENT.

PART 4: LYMPH NODES, RIGHT PELVIC, DISSECTION -
FIVE LYMPH NODES, NO TUMOR PRESENT (0/5).

PART 5: ABDOMINAL PERITONEUM, LEFT, BIOPSY -
FIBROADIPOSE TISSUE, NO TUMOR PRESENT.

PART 6: LYMPH NODES, RIGHT PELVIC, BIOPSY -
SEVEN LYMPH NODES, NO TUMOR PRESENT (0/7).

PART 7: LYMPH NODES, RIGHT PERI-AORTIC, DISSECTION -
FOUR LYMPH NODES, NO TUMOR PRESENT (0/4).

PART 8: LYMPH NODES, LEFT PERI-AORTIC, DISSECTION -
THREE LYMPH NODES, NO TUMOR PRESENT (0/3).

PART 9: APPENDIX, APPENDECTOMY -
BENIGN APPENDIX WITH FOCAL FIBROUS OBLITERATION OF THE LUMEN.

COMMENT:

The typical biphasic pattern of carcinosarcoma is seen in approximately 20% of this tumor. The carcinomatous component forms gland with high-grade nuclei and focal squamous differentiation. The remainder 80% of the tumor shows a high-grade sarcomatous component with areas of chondroid / myxoid matrix. Furthermore, although a few tumor cells are seen in underlying myometrial blood vessels, they are interpreted as "section artifact"; definite lymphovascular space invasion is not seen.

The companion pelvic wash is negative for malignant cells.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA : HYSTERECTOMY

TUMOR TYPE:	Carcinosarcoma (malignant mixed Mullerian tumor)
TUMOR SIZE:	Maximum dimension: 72 mm
PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:	Anterior endomyometrium: 10 %, Posterior endomyometrium: 10 % Less than 1/2 thickness of myometrium
DEPTH OF INVASION:	No
ANGIOLYMPHATIC INVASION:	No
LYMPH NODES POSITIVE:	Number of lymph nodes positive:: 0
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 19
T STAGE, PATHOLOGIC:	pT1a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	Not applicable
FIGO STAGE:	IA
Comment:	The tumor is large (7.2 cm) but is attached to the endometrium via a short pedicle and therefore endometrial surface involvement is minimal.

Pathologic Discrepancy		✓
Staging Discrepancy		✓
Secondary Discrepancy		✓
Specimen Discrepancy		✓

Source: NCI Genomic Data Commons file 2aca11d9-0827-47e5-97ce-8148593d32e5 (TCGA-N6-A4V9.3E0AABEC-8BE5-455F-A3AE-978273210E67.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).